Surgical pathology report (de-identified scan), TCGA case TCGA-05-4427, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4427-01A (Primary Tumor).

██████████

Main diagnosis/diagnoses:

Large peripheral to central, histologically predominantly undifferentiated mixed large-cell and polymorphocellular adenocarcinoma of the left upper lobe of the lung. TNM classification on the basis of this material pT2 pN1 R0, stage IIB. C34.1 M8255/3, G3.

Comment/supplementary remark:

Histologically, the large-cell and polymorphocellular solid component of the carcinoma predominates, with a clear-cell appearance in small sections and the possibility of a neuroendocrine differentiation (immunohistochemical analysis to follow). In all likelihood, it is a primary peripheral carcinoma of the lung that has invaded the overlying visceral pleura to a minimal extent and also shows central bronchopulmonary and hilar lymph node metastases. The other hilus lymph nodes and other lymph nodes removed are tumor-free

Result of immunohistochemical analysis. A high proportion of tumor cells positive for low molecular weight keratins ██████████ and a small proportion also for high molecular weight keratins ██████████. Relatively high proportion positive for TTF1. Negative for synaptophysin and NCAM.

The tumor classification of mixed-type adenocarcinoma of the lung is thus confirmed.

Source: NCI Genomic Data Commons file b1a1eb9c-59ac-44fd-b3b2-6e6a5a5d68a8 (TCGA-05-4427.06C7CDB1-5048-4C75-9002-090997275EFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).